Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA39, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA39-01A (Primary Tumor).

Surgery Date:

Male

DIAGNOSIS:

A. Peritoneal nodule, biopsy: Negative for tumor.

B. Gallbladder, cholecystectomy: Mild chronic cholecystitis.

C. Liver, left lobe, partial hepatectomy: Cholangiocarcinoma, grade 4 (of 4), is identified forming multiple masses (ranging in size from 0.2 cm to 0.8 cm in greatest dimension) replacing approximately 90% of the left liver lobe. The tumor is confined to hepatic parenchyma. The tumor growth pattern is mass-forming. The hepatic parenchymal resection margin is negative for tumor (minimum tumor free margin, 0.9 cm). The bile duct margin cannot be assessed. Left portal vein is involved by tumor.

No lymph node

metastasis are identified in multiple (10) regional lymph nodes.

With available surgical material [AJCC pT2bN0] (7th edition, 2009).

The tumor cells are positive with MOC-31, and are negative with CK7,

CK 20 and in situ hybridization testing for albumin.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

9/3/8/14

Source: NCI Genomic Data Commons file a7f7594d-36b4-445e-a6af-3b7560fdb6da (TCGA-W5-AA39.733CC9D1-7D35-4976-9CD9-B8B8542313E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).